CCDI case PBCEMR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4d8c46aa-f801-4cd0-88dc-0577ce3becd2

Demographics
Sex at birth: male; Race: american indian or alaska native; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.4 years (6,342 days).

Biospecimens (3 samples)
- Sample 0DQ55F: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ55Q: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DQ55V: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
